Somatic mutation profile of tumor specimen TARGET-10-PASSEF-09A (aliquot TARGET-10-PASSEF-09A-01D) from TARGET case TARGET-10-PASSEF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,806 days).
Specimen TARGET-10-PASSEF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84319343-7c7a-49f3-bfa9-c70ac634452f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASSEF-10A (Blood Derived Normal), aliquot TARGET-10-PASSEF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad402c8d-3cb6-4fb5-90c4-0e68164f4b88

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.6266G>A p.R2089Q (on ENST00000367573 / NM_001205293.3; = p.R2046Q on NM_000721.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs779786799, COSV62385435; called by muse, mutect2, varscan2
- FBXW7 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as COSV55901296, COSV55941317; called by muse, mutect2, varscan2
- HNRNPM | c.1981C>A p.P661T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55312537; called by muse, mutect2, varscan2
- MEP1A | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs567742042; called by muse, varscan2
- PSD3 | c.2300G>A p.R767H (on ENST00000440756; = p.R766H on NM_015310.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs376989905; called by muse, mutect2, varscan2
- SPG7 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.54); catalogued as COSV51948541; called by muse, mutect2, varscan2
- TINAG | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs766001132, COSV52507046; called by muse, mutect2, varscan2
- UBR3 | c.4099G>A p.A1367T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55846057; called by muse, mutect2, varscan2
- ZP1 | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2
- ADAMTS16 | c.3057G>A p.S1019= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs752743384, COSV56989344; called by muse, mutect2, varscan2
- LRRC8E | c.624G>A p.A208= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs369723392; called by muse, mutect2, varscan2
- IGHV3-20 | chr14:106210935 ins GACA | 3'Flank (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- RABL2B | c.137+78C>T | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.34523-330A>T | Intron (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- USP3 | c.1216-103T>C | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
